Somatic mutation profile of tumor specimen TCGA-AN-A0FJ-01A (aliquot TCGA-AN-A0FJ-01A-11W-A019-09) from TCGA case TCGA-AN-A0FJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.0 years (21,910 days).
Specimen TCGA-AN-A0FJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d3293e-8673-4c4e-9f69-642842b223be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FJ-10A (Blood Derived Normal), aliquot TCGA-AN-A0FJ-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c770841f-bf63-48bb-9de7-3259a30f7e54

The open-access MAF lists 102 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 5, Frame Shift Del 5, Intron 3, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 325/546 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV104381503, COSV54960601, COSV54968673; called by muse, mutect2, varscan2
- AGBL5 | c.2556_2559del p.S853Tfs*27 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as rs754247845; called by mutect2, pindel, varscan2
- AMIGO2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs140364757; called by muse, mutect2, varscan2
- ANKS4B | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61140507; called by muse, mutect2, varscan2
- ASH2L | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV51702088; called by muse, mutect2, varscan2
- BRF1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758735678, COSV59270451; called by muse, mutect2, varscan2
- CCDC110 | c.172-1G>C p.X58_splice | Splice Site (SNP) | VAF 20/32 reads (63%) | catalogued as COSV56873689; called by muse, mutect2, varscan2
- CD2 | c.150G>C p.M50I | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV65643486; called by muse, mutect2, varscan2
- CDK6 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 7/207 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99721258; called by muse, mutect2
- COBLL1 | c.2825C>G p.S942C (on ENST00000392717; = p.S904C on NM_014900.5) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52077361; called by muse, mutect2, varscan2
- COL13A1 | c.1505G>A p.R502H (on ENST00000398978 / NM_001130103.2; = p.R445H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371347973; called by muse, mutect2, varscan2
- COPS8 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV62976887; called by muse, mutect2, varscan2
- DIP2A | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59488144; called by muse, mutect2, varscan2
- DNAJC6 | c.1260C>A p.Y420* | Nonsense Mutation (SNP) | VAF 96/239 reads (40%) | catalogued as COSV54782689; called by muse, mutect2, varscan2
- DOCK7 | c.4755G>C p.E1585D (on ENST00000635253 / NM_001367561.1; = p.E1554D on NM_033407.3) | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV52023397; called by muse, mutect2, varscan2
- DYNLT3 | c.251G>C p.C84S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1256302320, COSV66079172; called by muse, mutect2, varscan2
- EFEMP1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as COSV62615456, COSV62618112; called by muse, mutect2, varscan2
- EIF2AK3 | c.3150G>T p.E1050D | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57552692; called by muse, mutect2, varscan2
- EPHA7 | c.2683C>G p.R895G | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs1035177735, COSV65179262, COSV65185064, COSV65190393; called by muse, mutect2, varscan2
- FBXL4 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV57750401; called by muse, mutect2, varscan2
- FBXL7 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs532860622, COSV61654202; called by muse, mutect2, varscan2
- HAUS8 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53727624; called by muse, mutect2, varscan2
- HDAC1 | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61482486; called by muse, mutect2, varscan2
- HEATR3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV53529336, COSV53531955; called by muse, mutect2, varscan2
- IPO9 | c.2938G>T p.E980* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | catalogued as COSV100843439; called by muse, mutect2
- ITGA11 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs754150729, COSV59882527; called by muse, mutect2, varscan2
- ITIH5 | c.2580C>G p.S860R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); catalogued as rs767409400, COSV99904692; called by muse, mutect2
- KCNH5 | c.1348G>T p.V450L | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV59780230; called by muse, mutect2, varscan2
- KIF17 | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV99929068; called by muse, mutect2, varscan2
- KIF5A | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV54059779; called by muse, mutect2, varscan2
- LGI3 | c.960C>G p.D320E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV60444466; called by muse, mutect2, varscan2
- MGAT4C | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs765452856, COSV59835101, COSV59836681; called by muse, mutect2, varscan2
- MICAL2 | c.4259G>T p.S1420I | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV56289088; called by muse, mutect2, varscan2
- MPHOSPH8 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.057); catalogued as COSV64058038; called by muse, mutect2, varscan2
- MTMR2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60582360; called by muse, mutect2, varscan2
- MUC16 | c.25146G>T p.M8382I | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV67479280, COSV67498700; called by muse, mutect2, varscan2
- MYH14 | c.1043C>G p.T348R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51832276, COSV51833219; called by muse, mutect2, varscan2
- MYOM3 | c.4072G>A p.V1358I | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs768039253, COSV58389074; called by muse, mutect2, varscan2
- NIPBL | c.2675G>T p.S892I | Missense Mutation (SNP) | VAF 139/514 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV56967918; called by muse, mutect2, varscan2
- NOD2 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.148); catalogued as COSV56054103; called by muse, mutect2, varscan2
- OBI1 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 128/336 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.399); catalogued as COSV56147871; called by muse, mutect2, varscan2
- OR1A2 | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 103/185 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV67936888; called by muse, mutect2, varscan2
- OR5H1 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 188/545 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV63403619; called by muse, mutect2, varscan2
- PBX4 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs139542458; called by muse, mutect2, varscan2
- PFKFB2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs372621164; called by muse, mutect2, varscan2
- PHF8 | c.1942G>C p.D648H (on ENST00000357988 / NM_001184896.1; = p.D612H on NM_015107.3) | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs782411309, COSV57688686; called by muse, mutect2, varscan2
- PLA2G4F | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV51829811; called by muse, mutect2, varscan2
- PLCL2 | c.1623C>G p.D541E (on ENST00000615277 / NM_001144382.2; = p.D415E on NM_015184.5) | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.163); catalogued as COSV101196750; called by muse, mutect2
- PON3 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 130/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55702267, COSV99672435; called by muse, mutect2, varscan2
- POTEF | c.225T>G p.S75R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.307); catalogued as rs755458117, COSV62539465; called by mutect2, varscan2
- PRKDC | c.6903G>T p.Q2301H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV58065995; called by muse, varscan2
- PRSS38 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV64542104; called by muse, mutect2, varscan2
- PRSS38 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV64542110; called by muse, mutect2, varscan2
- RFX7 | c.2555C>T p.T852I (on ENST00000559447 / NM_001368074.1; = p.T949I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57969396; called by muse, mutect2, varscan2
- ROR1 | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.08); catalogued as COSV64287918, COSV64293908; called by muse, mutect2, varscan2
- SLC38A11 | c.415G>A p.V139I (on ENST00000409149 / NM_001351539.1; = p.V117I on NM_173512.2) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs1220356976, COSV100366890; called by muse, mutect2
- SLC9C2 | c.2024A>T p.E675V | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100876772, COSV100876799; called by muse, mutect2, varscan2
- SNRPC | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV55076525; called by muse, mutect2, varscan2
- SP1 | c.49A>T p.I17F (on ENST00000327443 / NM_138473.3; = p.I10F on NM_003109.1) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.227); catalogued as COSV59405404; called by muse, mutect2, varscan2
- SUGP1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55924461, COSV99895329; called by muse, mutect2, varscan2
- TAOK1 | c.654A>G p.L218= | Splice Region (SNP) | VAF 8/94 reads (9%) | catalogued as rs765938895, COSV55600801; called by muse, mutect2
- THSD7B | c.2252G>A p.R751K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV55743830; called by muse, mutect2, varscan2
- TMEM270 | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs868909794, COSV57639918; called by muse, mutect2, varscan2
- TP53 | c.469_470insC p.V157Afs*24 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as COSV52917307, COSV53710000; called by pindel, varscan2
- TRAPPC2 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV62897215; called by muse, mutect2, varscan2
- TRIT1 | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV57547409, COSV57547678; called by muse, mutect2, varscan2
- TTN | c.59981G>C p.R19994P (on ENST00000591111; = p.R12570P on NM_003319.4) | Missense Mutation (SNP) | VAF 46/337 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV60074466, COSV60388057; called by muse, mutect2, varscan2
- TTPA | c.366G>C p.W122C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52646790, COSV52648687, COSV99478520; called by muse, mutect2, varscan2
- ZGLP1 | c.783T>A p.C261* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV67059697; called by muse, mutect2, varscan2
- ZNF626 | c.1191C>G p.Y397* | Nonsense Mutation (SNP) | VAF 169/450 reads (38%) | catalogued as COSV74131110; called by muse, mutect2, varscan2
- ZNF71 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs772545203, COSV60147088; called by muse, mutect2, varscan2
- ATP10B | c.1243_1256del p.C415Hfs*15 | Frame Shift Del (DEL) | VAF 65/132 reads (49%) | called by mutect2, pindel, varscan2
- IRS1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- NIF3L1 | c.356_360del p.N119Sfs*11 (on ENST00000409020 / NM_001369444.1; = p.N92Sfs*11 on NM_021824.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/217 reads (9%) | called by mutect2*, pindel, varscan2*
- NIF3L1 | c.358_362del p.V121Yfs*9 (on ENST00000409020 / NM_001369444.1; = p.V94Yfs*9 on NM_021824.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/233 reads (11%) | called by mutect2, varscan2
- ZFP36L1 | c.943_989del p.G315Qfs*8 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | called by mutect2, pindel
- AFF1 | c.42G>A p.L14= | Silent (SNP) | VAF 183/279 reads (66%) | catalogued as COSV57125116; called by muse, mutect2, varscan2
- ALMS1 | c.1962A>T p.P654= | Silent (SNP) | VAF 13/439 reads (3%) | catalogued as COSV100042530; called by muse, mutect2
- DNAH5 | c.4299T>C p.L1433= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs781219274, COSV99450080; called by muse, mutect2, varscan2
- ECHDC1 | c.591C>A p.T197= (on ENST00000531967 / NM_001139510.1; = p.T191= on NM_001002030.2) | Silent (SNP) | VAF 77/124 reads (62%) | catalogued as rs1223586622, COSV58934543; called by muse, mutect2, varscan2
- EIF2B3 | c.1224C>T p.V408= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs1435251884, COSV64518966; called by muse, mutect2, varscan2
- FARP1 | c.2067C>T p.L689= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs754628892, COSV60349776; called by muse, mutect2, varscan2
- FDPS | c.1140C>T p.F380= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as COSV52743210; called by muse, mutect2, varscan2
- HIP1 | c.282G>A p.K94= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100417552; called by muse, mutect2
- IPMK | c.957G>A p.A319= | Silent (SNP) | VAF 52/298 reads (17%) | catalogued as rs766938208, COSV64244755; called by muse, mutect2, varscan2
- MAN2B2 | c.2865C>T p.L955= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- NAP1L2 | c.552G>A p.E184= | Silent (SNP) | VAF 140/218 reads (64%) | catalogued as rs1349614084, COSV65173161; called by muse, varscan2
- PDE4DIP | c.6078G>C p.G2026= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- PLA2G4A | c.567G>T p.V189= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV66557468; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1377C>T p.F459= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs200296312, COSV53453394; called by muse, mutect2, varscan2
- PQBP1 | c.633C>T p.D211= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs781873995, COSV54429666; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAB40A | c.453C>T p.T151= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100420935; called by muse, mutect2
- SCUBE2 | c.1056A>G p.G352= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1187914526, COSV58547215; called by muse, mutect2, varscan2
- SLC44A5 | c.930G>A p.G310= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV63775679; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1206A>G p.S402= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as COSV50562855; called by muse, mutect2, varscan2
- TRAPPC9 | c.429G>A p.T143= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs369511113; called by muse, mutect2
- USP34 | c.609A>G p.V203= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1304262523, COSV68407595; called by muse, mutect2, varscan2
- ZNF578 | c.78C>T p.F26= | Silent (SNP) | VAF 196/388 reads (51%) | catalogued as COSV69737799; called by muse, varscan2
- C16orf91 | c.*99C>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | catalogued as COSV59951057; called by muse, mutect2, varscan2
- DST | c.4297-3537G>A | Intron (SNP) | VAF 96/213 reads (45%) | catalogued as rs1390801517, COSV55044002; called by muse, mutect2, varscan2
- POLR2F | c.453-14998G>T | Intron (SNP) | VAF 37/111 reads (33%) | catalogued as COSV61006323; called by muse, mutect2, varscan2
- TOMM20 | c.121+709G>A | Intron (SNP) | VAF 40/92 reads (43%) | catalogued as COSV64013510, COSV64013525; called by muse, mutect2, varscan2
